Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2P, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2P-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-O-3
Histiocytoma, fibrous
malignant pleomorphic
8830/3
Site: thigh NOS
049.2
CpW 3/10/14

Clinical Diagnosis & History:

with pleomorphic MFH right anterolateral thigh.

Specimens Submitted:

1: SP: Radical resection of right thigh sarcoma

DIAGNOSIS:

- 1) SOFT TISSUE, RIGHT THIGH; RADICAL RESECTION:
- UNDIFFERENTIATED HIGH GRADE PLEOMORPHIC SARCOMA (PLEOMORPHIC MALIGNANT FIBROUS HISTIOCYTOMA) INVOLVING FIBROADIPOSE TISSUE AND SKELETAL MUSCLE.
- TUMOR MEASURES 14 CM GREATEST DIMENSION AND SHOWS ABOUT 50% NECROSIS (GROSS ESTIMATE).
- TUMOR COMES WITHIN 0.15 CM OF DEEP AND 0.5 CM OF LATERAL MARGIN (OTHER MARGINS ARE WIDELY CLEAR).
- CUTANEOUS SCAR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh labeled "radical resection of right thigh sarcoma" and consists of a pink-tan hemorrhagic soft tissue mass with overlying skin measuring 28.5 x 14.5 x 9.1 cm altogether; overlying skin measures 7.5 x 6.7 cm. There is a central healed linear scar measuring 3.9 cm. The specimen is oriented with sutures, short stitch designating the superior margin and long stitch lateral margin. The specimen is inked: superior green, lateral blue, medial yellow, deep black and inferior red. Sections show a variegated tumor measuring 14 x 12.5 x 10.5 cm which is

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
solid and cystic (the cystic component approximately 30%) with extensive
necrosis (approximately 50% of the tumor). The tumor is 2 cm from the
anterior skin, 5 cm from the superior margin, 8.5 cm from the inferior
margin, 0.5 cm from the lateral margin, 0.5 cm from the deep margin and 0.9
cm from the medial margin. Photographs are taken and a portion of the
specimen is submitted for TPS. Representative sections are submitted.

Summary of sections

S-superior margin
I-inferior margin
L-lateral margin
M-medial margin
A-anterior skin
D-deep/posterior margin
T-tumor

Summary of Sections:

Part 1: SP: Radical resection of right thigh sarcoma

Block	Sect. Site	PCs
1	A	0
1	D	0
1	i	0
1	L	0
1	M	0
1	s	0
8	T	0

** End of Report **

W 1/22/14

Prior Tx

Source: NCI Genomic Data Commons file 329f4a22-c6b8-4599-905a-edb0767df0ec (TCGA-DX-AB2P.8B5E98BC-31A7-4287-A6A9-868F14190752.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).